Somatic mutation profile of tumor specimen 0DR20L from CCDI case PBCFKK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 6.3 years (2,288 days).
Specimen 0DR20L: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0abc2e0f-c49b-4bf8-9317-f5f490e43ed1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR1YP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6b5a963-c2b4-4988-9b1c-282ce9acbb5d

The open-access MAF lists 13 somatic variants for this specimen: 6 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 4, Splice Region 2, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- THPO | c.434-5C>G | Splice Region (SNP) | VAF 351/871 reads (40%) | catalogued as rs1319111971; called by muse, mutect2, varscan2
- FBXO10 | c.1885G>A p.V629M | Missense Mutation (SNP) | VAF 235/602 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OGT | c.531G>A p.K177= | Splice Region (SNP) | VAF 20/413 reads (5%) | called by muse, mutect2
- RPSA | c.882G>T p.W294C | Missense Mutation (SNP) | VAF 174/446 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- SBF2 | c.3587G>T p.R1196L | Missense Mutation (SNP) | VAF 157/331 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- USH2A | c.4186G>C p.G1396R | Missense Mutation (SNP) | VAF 296/635 reads (47%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- CDH23 | c.8733C>T p.D2911= | Silent (SNP) | VAF 206/457 reads (45%) | catalogued as rs781649648; called by muse, mutect2, varscan2
- DYNC1I1 | c.1650C>T p.C550= | Silent (SNP) | VAF 40/998 reads (4%) | called by muse, mutect2
- HAL | c.1593C>T p.H531= | Silent (SNP) | VAF 292/688 reads (42%) | catalogued as rs185963433; called by muse, mutect2, varscan2
- NDUFB6 | c.45G>C p.L15= | Silent (SNP) | VAF 20/631 reads (3%) | called by muse, mutect2
- PRKCQ | c.1257C>T p.D419= | Silent (SNP) | VAF 270/656 reads (41%) | catalogued as rs746114853, COSV99577227; called by muse, mutect2, varscan2
- PAFAH1B3 | c.408+45G>A | Intron (SNP) | VAF 108/256 reads (42%) | called by muse, mutect2, varscan2
- UBXN4 | chr2:135741835 C>T | 5'Flank (SNP) | VAF 35/69 reads (51%) | catalogued as rs1370036912; called by muse, mutect2, varscan2
